Gene-level copy-number profile of tumor specimen TCGA-61-2012-01A from TCGA case TCGA-61-2012, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G2; Age at diagnosis: 81.7 years (29,830 days).
Specimen TCGA-61-2012-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.4b634cdf-e7d6-4ac5-8128-d29baeb34bf8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-2012-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/64d7e33f-b0bd-4a36-af23-05e3b3b52af8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,723; copy number 2: 21,626; copy number 3: 18,376; copy number 4: 11,187; copy number 5: 3,213; copy number 6: 1,691; copy number 7: 521; copy number 8: 121; copy number 9: 56; copy number 10: 892; copy number 11: 223; copy number 12: 131; copy number 15: 9; copy number 19: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-2012-01A-01D-0663-01): tumor purity 0.58, ploidy 2.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,895 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,754,216–40,876,670, 83 genes, copy number 6 (broad region; genes not listed).
- chr1:46,340,177–47,050,751, 26 genes, copy number 6 (within-gene range 3–6): NSUN4, AL122001.1, FAAH, FAAHP1, LINC01398, DMBX1, TMEM275, MKNK1-AS1, KNCN, MKNK1, MOB3C, ATPAF1, NENFP1, TEX38, EFCAB14-AS1, EFCAB14, AL593856.1, CYP4B1, CYP4Z2P, TUBAP8, CYP4A11, CYP4A26P, CYP4A43P, CYP4A27P, CYP4A44P, CYP4X1.
- chr1:143,343,180–156,728,766, 627 genes, copy number 6 (broad region; genes not listed).
- chr2:43,001,355–43,132,482, 5 genes, copy number 5 (within-gene range 3–5): AC016735.1, LINC01819, LINC02590, RNU6-242P, LINC02580.
- chr2:112,275,597–113,756,693, 59 genes, copy number 6 (within-gene range 4–6): ZC3H6, NDUFB4P6, AC115115.1, RGPD8, VINAC1P, TTL, POLR1B, Y_RNA, CHCHD5, AC012442.2, AC012442.1, AC079922.1, AC079922.2, SLC20A1, NT5DC4, CKAP2L, IL1A, AC079753.2, IL1B, AC079753.1, XIAPP3, IL37, CDK8P2, IL36G, HMGN2P23, POLR2DP1, IL36A, IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4, FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7, RABL2A, SNRPA1P1, ACRP1, AC017074.2, AC017074.1, RNU6-744P, SLC35F5, MIR4782.
- chr2:114,260,050–227,387,949, 1,702 genes, copy number 5–11 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 10 (broad region; genes not listed).
- chr6:36,740,775–38,640,148, 37 genes, copy number 5: CPNE5, Z85996.2, Z85996.3, PPIL1, C6orf89, AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1, AL121574.1, ZFAND3, RN7SL285P, RNVU1-33, AL589655.1, BTBD9, AL033518.1, BTBD9-AS1, Y_RNA, AL079341.1.
- chr8:31,639,222–32,855,666, 6 genes, copy number 5 (within-gene range 2–5): NRG1, AC068931.1, NRG1-IT1, RNA5SP262, RNA5SP263, NRG1-IT3.
- chr8:41,509,593–41,578,421, 1 gene, copy number 6 (within-gene range 4–6): AC009630.1.
- chr8:41,529,218–53,242,683, 170 genes, copy number 6–10 (within-gene range 3–10) (broad region; genes not listed).
- chr10:5,122,087–43,525,217, 634 genes, copy number 5 (broad region; genes not listed).
- chr10:76,437,408–79,677,996, 52 genes, copy number 5–7: AC013286.1, AC024603.1, AC013738.1, ATP5MC1P8, KCNMA1, KCNMA1-AS1, KCNMA1-AS2, AL731575.1, KCNMA1-AS3, COX6CP15, RNA5SP321, AL731556.1, AL731556.2, RNU6-1266P, IMPDH1P5, AL450306.1, DLG5, AL391421.1, RN7SL284P, DLG5-AS1, H2AZP5, Metazoa_SRP, POLR3A, RPS24, GNAI2P2, AL731555.1, AC012560.1, LINC00595, AC010163.3, AC010163.1, AC010163.2, SNORA71, AL583852.1, AC016820.1, ZMIZ1-AS1, AL356753.1, ZMIZ1, PPIF, ZCCHC24, AL133481.1, TPRX1P1, AL133481.3, AL133481.2, EIF5AL1, BX248123.1, RPS12P18, SFTPA2, MBL3P, SFTPA3P, SFTPA1, LINC02679, AL132656.2.
- chr10:79,663,192–79,684,094, 2 genes, copy number 5: AL132656.3, AL132656.4.
- chr11:44,719,392–45,044,053, 5 genes, copy number 5 (within-gene range 3–5): TSPAN18-AS1, TSPAN18, TP53I11, LINC02685, AC068858.1.
- chr11:71,814,045–79,989,630, 246 genes, copy number 5–19 (broad region; genes not listed).
- chr12:66,767–47,706,030, 993 genes, copy number 5–12 (within-gene range 4–12) (broad region; genes not listed).
- chr14:102,362,941–104,294,921, 73 genes, copy number 5 (broad region; genes not listed).
- chr17:142,789–1,492,686, 42 genes, copy number 5 (within-gene range 1–5): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB, AC015853.2, VPS53, AC015853.3, AC015853.1, AC027455.1, RPS4XP17, TLCD3A, GEMIN4, DBIL5P, GLOD4, AC087392.3, MRM3, AC087392.4, AC087392.5, NXN, AC087392.2, AC087392.1, AC036164.1, TIMM22, ABR, MIR3183, Metazoa_SRP, AC016292.2, AC016292.1, AC144836.1, BHLHA9, TRARG1, YWHAE, AC032044.2, CRK, AC032044.1, MYO1C.
- chr17:1,995,614–7,833,744, 306 genes, copy number 5–11 (within-gene range 1–11) (broad region; genes not listed).
- chr18:24,321,686–49,851,059, 340 genes, copy number 6–11 (broad region; genes not listed).
- chr18:49,871,555–49,871,666, 1 gene, copy number 6: Y_RNA.
- chr18:58,044,226–80,097,088, 331 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr19:27,638,483–39,248,856, 410 genes, copy number 5–12 (broad region; genes not listed).
- chr20:5,937,228–6,780,246, 19 genes, copy number 5 (within-gene range 3–5): TRMT6, MCM8, AL035461.3, Y_RNA, AL035461.1, MCM8-AS1, AL035461.2, RN7SL498P, CRLS1, LRRN4, AL118505.1, FERMT1, TARDBPP1, AL109618.1, AL109618.2, AL109618.3, CASC20, LINC01713, BMP2.
- chr20:32,631,625–33,111,751, 15 genes, copy number 6 (within-gene range 4–6): C20orf203, FO393400.1, BAK1P1, COMMD7, DNMT3B, MAPRE1, AL035071.2, AL035071.1, EFCAB8, SUN5, BPIFB2, BPIFB6, PUDPP3, BPIFB3, BPIFB4.

Autosomal genes at a single copy (total copy number 1): 1,723. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
